Gene-level copy-number profile of tumor specimen ALCH-B3JN-TTP1-A from ALCHEMIST case ALCH-B3JN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.4 years (29,352 days).
Specimen ALCH-B3JN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 128a128b-7f95-465b-8577-d524459d2dc2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3JN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/075f0bdf-cdf7-4ca9-864d-274996dd4093

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 15,756; copy number 2: 38,965; copy number 3: 3,269; copy number 4: 143; copy number 5: 16; copy number 6: 69; copy number 7: 9; copy number 8: 61; copy number 9: 3; copy number 11: 26.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,692,734–20,733,952, 3 genes (within-gene range 0–1): AL663074.2, SH2D5, AL663074.1.
- chr7:45,816,216–45,843,740, 4 genes: CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr9:138,129,399–138,143,864, 2 genes: AL591424.1, IL9RP1.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr15:25,180,497–25,215,622, 20 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25.
- chr16:46,578,591–46,698,394, 8 genes: SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6.
- chr16:81,100,875–81,220,370, 3 genes (within-gene range 0–1): PKD1L2, RNU6-1191P, AC092718.9.
- chr18:74,495,816–74,523,454, 2 genes (within-gene range 0–2): CNDP2, AC009704.2.
- chr22:18,873,543–19,034,564, 15 genes: FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2, DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C, CA15P1.
- chr22:19,045,256–19,061,843, 4 genes (within-gene range 0–1): Y_RNA, DGCR11, AC004461.1, AC004461.2.
- chr22:23,059,415–23,145,021, 4 genes (within-gene range 0–1): RSPH14, GNAZ, Metazoa_SRP, U7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 184 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes, copy number 6–9 (within-gene range 2–9): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr8:36,987,977–36,988,412, 1 gene, copy number 9: AC090453.1.
- chr8:38,105,493–40,520,158, 58 genes, copy number 5–11: ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:41,032,892–41,309,473, 6 genes, copy number 7: RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr9:137,224,635–137,236,555, 3 genes, copy number 5: CYSRT1, RNF224, SLC34A3.
- chr19:44,643,798–44,666,162, 1 gene, copy number 7 (within-gene range 4–7): PVR.
- chr19:44,662,278–44,684,359, 2 genes, copy number 7 (within-gene range 4–7): CEACAM19, AC243964.4.
- chr19:44,747,705–45,863,194, 67 genes, copy number 6 (broad region; genes not listed).
- chr22:21,938,269–22,329,122, 42 genes, copy number 8 (within-gene range 1–8): PPM1F-AS1, TOP3B, PRAMENP, IGLVI-70, IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1, AC245060.6, AC245060.5, AC245060.2, AC245060.7, AC245060.4, IGLV5-52.

Autosomal genes at a single copy (total copy number 1): 15,720. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
